CCDI case PBCLFI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3c4b7905-fff2-47fa-823b-51c38ef2b20c

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.4 years (2,339 days).

Biospecimens (3 samples)
- Sample 0DUIWP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUIWZ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUIXL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
